Gene-level copy-number profile of tumor specimen TCGA-P3-A6SX-01A from TCGA case TCGA-P3-A6SX, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 67.7 years (24,715 days).
Specimen TCGA-P3-A6SX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.734b7630-c24e-44f5-a7a8-311da4a5b3ce.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-P3-A6SX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/28b4c045-554e-45c6-bd07-55dab99970a8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 10,574; copy number 2: 35,348; copy number 3: 10,916; copy number 4: 2,576; copy number 5: 276; copy number 8: 6; copy number 10: 46; copy number 11: 66; copy number 17: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-P3-A6SX-01A-11D-A34I-01): tumor purity 0.64, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 406 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:242,975,005–246,691,821, 70 genes, copy number 5 (broad region; genes not listed).
- chr4:12,223,445–13,648,400, 17 genes, copy number 8–17: LINC02270, RNU6-578P, ECM1P2, AC093809.1, AC007370.2, AC007370.1, U6, HSP90AB2P, RAB28, AC006445.3, LINC01097, NKX3-2, LINC01096, BOD1L1, MIR5091, AC006445.2, AC006445.1.
- chr4:13,777,377–13,782,157, 1 gene, copy number 17: AC007126.1.
- chr4:69,721,167–74,455,005, 84 genes, copy number 5 (broad region; genes not listed).
- chr7:92,112,153–99,408,597, 141 genes, copy number 5–10 (within-gene range 3–10) (broad region; genes not listed).
- chr11:68,460,731–68,615,334, 1 gene, copy number 11 (within-gene range 3–11): PPP6R3.
- chr11:68,612,899–71,670,297, 85 genes, copy number 5–11 (broad region; genes not listed).
- chr14:85,202,849–85,654,428, 7 genes, copy number 5 (within-gene range 4–5): AL357172.1, AL049775.2, LINC02329, LINC00911, AL049775.1, AL049775.3, FLRT2.

Autosomal genes at a single copy (total copy number 1): 8,153. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
